Somatic mutation profile of tumor specimen ALCH-B1JZ-TTP1-A (aliquot ALCH-B1JZ-TTP1-A-2-0-D-A714-36) from ALCHEMIST case ALCH-B1JZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.1 years (25,969 days).
Specimen ALCH-B1JZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a631ba1-8f4e-4a24-830e-b4e7afb728d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1JZ-NB1-A (Blood Derived Normal), aliquot ALCH-B1JZ-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3779c142-27d9-4aea-82d5-4115c2b1e029

The open-access MAF lists 810 somatic variants for this specimen: 567 protein-altering or splice-affecting, 155 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 475, Silent 155, Intron 45, Nonsense Mutation 41, Frame Shift Del 19, Splice Site 17, RNA 16, 5'UTR 10, 3'UTR 9, Splice Region 8, 5'Flank 5, Frame Shift Ins 4.

Variants (750 of 810; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373072443, CM098044; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 49/239 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55121642; called by muse, mutect2
- ADAMDEC1 | c.647C>A p.A216E | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV56474878; called by muse, mutect2, varscan2
- ADAMTS12 | c.4648del p.Q1550Rfs*3 | Frame Shift Del (DEL) | VAF 35/217 reads (16%) | catalogued as COSV100711393; called by mutect2, pindel, varscan2
- ADAMTS19 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV50798669; called by muse, mutect2, varscan2
- ADGRB3 | c.3042G>C p.W1014C | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53250784, COSV99485063; called by muse, mutect2, varscan2
- AHSG | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as rs1204732359, COSV56608604; called by muse, mutect2, varscan2
- AKT1 | c.1264A>C p.S422R | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62575416; called by muse, mutect2, varscan2
- ANKRD61 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs56841160; called by muse, mutect2, varscan2
- ANXA6 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.183); catalogued as rs781639287; called by muse, mutect2, varscan2
- AOC2 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV99513514; called by muse, mutect2
- AP002512.3 | c.1074del p.I359Sfs*13 | Frame Shift Del (DEL) | VAF 38/179 reads (21%) | catalogued as COSV54405528; called by mutect2, pindel, varscan2
- APBA1 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs1229401278, COSV55227510; called by muse, mutect2, varscan2
- ASPM | c.6796G>T p.A2266S | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200800956; called by muse, mutect2, varscan2
- BACH2 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV57595175; called by muse, mutect2, varscan2
- BMP4 | c.975G>T p.W325C | Missense Mutation (SNP) | VAF 23/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM111218; called by muse, mutect2
- BPNT1 | c.628A>G p.M210V | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1374862797; called by muse, mutect2
- BPNT2 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.14); catalogued as rs1223820299; called by muse, mutect2, varscan2
- BRD1 | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1436656382, COSV99349898; called by muse, mutect2
- C1QTNF3 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as COSV51468169; called by muse, mutect2, varscan2
- C1orf87 | c.1542del p.S515Pfs*2 | Frame Shift Del (DEL) | VAF 28/194 reads (14%) | catalogued as COSV64598405; called by mutect2, pindel*, varscan2
- C6 | c.2611del p.E871Kfs*39 | Frame Shift Del (DEL) | VAF 81/382 reads (21%) | catalogued as COSV54707096; called by mutect2, pindel, varscan2
- CA10 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53345322; called by muse, mutect2, varscan2
- CA7 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754532644, COSV58156659; called by muse, mutect2, varscan2
- CCDC114 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs768112148; called by muse, mutect2, varscan2
- CCKBR | c.194del p.F65Sfs*2 | Frame Shift Del (DEL) | VAF 37/154 reads (24%) | catalogued as COSV58104324; called by mutect2, pindel, varscan2
- CDH18 | c.2066G>T p.R689M | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56921936; called by muse, mutect2, varscan2
- CDH9 | c.2342A>G p.Y781C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765236056, COSV50515375, COSV50523238; called by mutect2, varscan2
- CDK14 | c.805G>T p.E269* (on ENST00000380050 / NM_001287135.2; = p.E251* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 22/174 reads (13%) | catalogued as COSV56030325; called by muse, mutect2, varscan2
- CIC | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.09); catalogued as rs1432205915; called by muse, mutect2, varscan2
- CNTN4 | c.2238C>G p.I746M | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV61872216; called by muse, mutect2, varscan2
- CNTNAP5 | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 26/269 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV70515091, COSV70518246; called by muse, mutect2, varscan2
- COL6A5 | c.4608A>G p.Q1536= | Splice Region (SNP) | VAF 34/149 reads (23%) | catalogued as rs1445634380; called by muse, varscan2
- CRYZ | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61717888; called by muse, mutect2, varscan2
- CSF2RA | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV62625702; called by muse, mutect2
- CTLA4 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV99865031; called by muse, varscan2
- CXorf66 | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100983822; called by muse, mutect2, varscan2
- CYB5R4 | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859625; called by mutect2, varscan2
- CYP4B1 | c.1477C>A p.R493S | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs371613738; called by muse, mutect2, varscan2
- DDC | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV63566150; called by muse, mutect2, varscan2
- DDX46 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.931); catalogued as COSV100844923, COSV62798909; called by muse, mutect2
- DDX54 | c.2431G>T p.A811S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV58374670; called by muse, mutect2, varscan2
- DDX60 | c.3606A>G p.I1202M | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV99062248; called by muse, mutect2
- DIP2A | c.3056G>A p.C1019Y | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.846); catalogued as rs1294915674, COSV100595503; called by muse, mutect2, varscan2
- DLC1 | c.2008C>T p.R670W (on ENST00000276297 / NM_001348081.2; = p.R233W on NM_006094.5) | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375672644; called by muse, mutect2, varscan2
- DMBT1 | c.1721C>A p.P574H | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1275809098; called by muse, mutect2
- DNAJC10 | c.849G>T p.L283F | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99899643; called by muse, mutect2, varscan2
- DYNC2H1 | c.1912A>T p.M638L | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV62102448; called by muse, mutect2
- EIF5B | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1015028157; called by muse, mutect2, varscan2
- ELFN1 | c.1781C>A p.A594E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as rs1007410261; called by muse, varscan2
- EN1 | c.1161C>A p.D387E | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV54631827; called by muse, varscan2
- ESCO1 | c.1247G>C p.G416A | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52520618; called by muse, mutect2
- ESM1 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV67319077; called by muse, mutect2, varscan2
- ETV5 | c.1477C>G p.L493V | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV60502323; called by muse, mutect2
- FAM131B | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM8A1 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.201); catalogued as rs939374504; called by muse, mutect2, varscan2
- FAM98C | c.334G>T p.G112* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as rs1272235696; called by muse, mutect2, varscan2
- FANCM | c.2084G>T p.R695M | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV57506963; called by muse, mutect2, varscan2
- FAT3 | c.11012G>C p.R3671P | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53106675, COSV99035396; called by muse, mutect2, varscan2
- FAT4 | c.2383C>A p.Q795K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.959); catalogued as rs1435245729; called by muse, mutect2, varscan2
- FGF6 | c.204G>C p.E68D | Missense Mutation (SNP) | VAF 21/355 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV57405271; called by muse, mutect2
- FOXC2 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs1367357869; called by muse, mutect2, varscan2
- FREM2 | c.7480G>T p.E2494* | Nonsense Mutation (SNP) | VAF 61/585 reads (10%) | catalogued as COSV99751190; called by muse, mutect2, varscan2
- FTHL17 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV63266556; called by muse, mutect2, varscan2
- FZD8 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as rs758634930; called by muse, mutect2, varscan2
- FZD8 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV65968620; called by muse, mutect2, varscan2
- GATA3 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV60519439; called by muse, mutect2, varscan2
- GATA5 | c.1148G>T p.R383M | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV53345176; called by muse, mutect2, varscan2
- GDPD3 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.788); catalogued as rs140159790; called by muse, mutect2, varscan2
- GMPR | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV52474096, COSV52475731; called by muse, mutect2, varscan2
- GRID2 | c.1330C>A p.R444S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56193336; called by muse, mutect2, varscan2
- GRIK2 | c.1060C>A p.R354S | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.633); catalogued as COSV59784426; called by muse, mutect2
- GRM7 | c.1306G>T p.V436F | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV100736498; called by muse, mutect2, varscan2
- GRXCR2 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 35/250 reads (14%) | catalogued as COSV100940004; called by muse, mutect2, varscan2
- HECW1 | c.2582C>T p.T861M | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs779442609, COSV67822270, COSV67840029; called by muse, mutect2
- HJV | c.350A>G p.H117R (on ENST00000336751 / NM_213653.4; = p.H4R on NM_145277.5) | Missense Mutation (SNP) | VAF 48/295 reads (16%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.966); catalogued as rs1553769733; called by muse, mutect2, varscan2
- HMCN2 | c.13567G>A p.D4523N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as rs946846684; called by muse, mutect2, varscan2
- HTR1A | c.731C>G p.A244G | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100109348; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.150C>A p.S50R | Missense Mutation (SNP) | VAF 66/574 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs764218621; called by mutect2, varscan2
- IGHV4-61 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 106/686 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as rs781906382; called by muse, varscan2
- IL17RC | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 52/184 reads (28%) | catalogued as rs2648623; called by muse, mutect2, varscan2
- IMPDH2 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1310959844, COSV58244664; called by muse, mutect2, varscan2
- INHBA | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54223942, COSV99638519; called by muse, mutect2
- IRAG2 | c.3072G>T p.E1024D (on ENST00000636465; = p.E69D on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV63140931; called by muse, mutect2, varscan2
- IRX1 | c.1391T>A p.L464Q | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV100116797; called by muse, varscan2
- ITGA8 | c.1523A>G p.Q508R | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1323213397, COSV100958878; called by muse, mutect2
- KCNA3 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63901969; called by muse, mutect2
- KCNB2 | c.1703C>A p.S568Y | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.349); catalogued as COSV73050310; called by muse, mutect2, varscan2
- KCNK9 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 20/403 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57279861, COSV57280788; called by muse, mutect2
- KCNMB1 | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV99210692; called by muse, mutect2, varscan2
- KIF2B | c.806C>A p.A269D | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs747891960; called by muse, mutect2, varscan2
- KIR2DL3 | c.294C>G p.Y98* | Nonsense Mutation (SNP) | VAF 94/282 reads (33%) | catalogued as rs1383245927; called by muse, mutect2, varscan2
- KL | c.2768C>A p.P923Q | Missense Mutation (SNP) | VAF 58/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101199215; called by muse, mutect2, varscan2
- KRT1 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs763145084; called by muse, mutect2, varscan2
- KRT71 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV57289252; called by muse, mutect2
- KRTAP10-9 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1326330087; called by muse, mutect2, varscan2
- KRTAP13-2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs766217527, COSV67761878; called by muse, mutect2, varscan2
- KRTAP19-1 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 34/203 reads (17%) | catalogued as rs757510085; called by muse, mutect2, varscan2
- KRTAP19-5 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 35/442 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.415); catalogued as COSV100478466, COSV61859758; called by muse, mutect2
- KSR1 | c.1300-1G>T p.X434_splice (on ENST00000644974 / NM_001367810.1; = p.X297_splice on NM_014238.2) | Splice Site (SNP) | VAF 53/193 reads (27%) | catalogued as COSV52031373; called by muse, mutect2, varscan2
- LCMT1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs1294679170; called by muse, mutect2, varscan2
- LMBR1L | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57267166, COSV57267339; called by muse, mutect2, varscan2
- LRP1B | c.7024C>G p.P2342A | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67268006; called by muse, mutect2, varscan2
- LRRC8B | c.1888C>T p.Q630* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV58377507, COSV58377547; called by muse, mutect2
- LVRN | c.679del p.D227Tfs*9 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as COSV100773732; called by mutect2, varscan2
- MAGEC1 | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs752999850, COSV53571509, COSV53574727; called by muse, mutect2, varscan2
- MAP2K4 | c.866A>C p.D289A | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62260352; called by muse, mutect2, varscan2
- MAP4K1 | c.1107C>T p.P369= | Splice Region (SNP) | VAF 15/45 reads (33%) | catalogued as rs1343764124; called by muse, mutect2, varscan2
- MAPRE2 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV100290952; called by muse, mutect2, varscan2
- MCFD2 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 32/453 reads (7%) | catalogued as CD031559; called by muse, mutect2
- MGAM2 | c.4459C>A p.Q1487K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1400308380; called by muse, mutect2, varscan2
- MGAM2 | c.4924-1G>T p.X1642_splice | Splice Site (SNP) | VAF 16/71 reads (23%) | catalogued as rs1311346442; called by muse, mutect2, varscan2
- MNDA | c.189C>A p.D63E | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.551); catalogued as COSV63739938; called by muse, varscan2
- MRAP | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV100353375; called by muse, mutect2
- NAGLU | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 30/451 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56795114; called by muse, mutect2
- NDST4 | c.1536+1G>C p.X512_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as COSV52136602; called by muse, mutect2, varscan2
- NDUFB10 | c.172_174del p.Y58del | In Frame Del (DEL) | VAF 19/154 reads (12%) | catalogued as rs747133070; called by pindel, varscan2
- NGDN | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs540927380, COSV101238918; called by muse, mutect2, varscan2
- NLGN4X | c.2428G>T p.G810* | Nonsense Mutation (SNP) | VAF 37/126 reads (29%) | catalogued as COSV52025924; called by muse, mutect2, varscan2
- NLGN4X | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1362464602, COSV52039844; called by muse, mutect2
- NLRC4 | c.1167C>A p.S389R | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV61594524; called by muse, mutect2, varscan2
- NOBOX | c.727C>G p.H243D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56197164; called by muse, mutect2
- NOS2 | c.2035-1G>A p.X679_splice | Splice Site (SNP) | VAF 13/103 reads (13%) | catalogued as COSV58227347; called by muse, mutect2
- NPAS2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs763172499, COSV100176495; called by muse, mutect2, varscan2
- NR1H4 | c.1100G>C p.R367P (on ENST00000551379 / NM_001206993.2; = p.R353P on NM_005123.4) | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as COSV51849217; called by muse, mutect2, varscan2
- NRXN3 | c.301C>A p.P101T (on ENST00000557594 / NM_001272020.2; = p.P733T on NM_004796.6) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99822201; called by muse, mutect2
- OLFM4 | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs764773781; called by muse, varscan2
- OR10AG1 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV100400205; called by muse, mutect2
- OR10C1 | c.703C>T p.R235C (on ENST00000622521; = p.R233C on NM_013941.3) | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs147036236, COSV65822212; called by muse, mutect2
- OR10S1 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.909); catalogued as rs756988059; called by muse, mutect2, varscan2
- OR11L1 | c.960C>A p.F320L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV63313830; called by mutect2, varscan2
- OR2L8 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.17); catalogued as COSV100594283; called by muse, mutect2, varscan2
- OR4F6 | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61027230; called by muse, mutect2, varscan2
- OR4N5 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs138121722; called by muse, mutect2, varscan2
- OR5T1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57302939; called by muse, mutect2
- OR5W2 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60618446; called by muse, mutect2, varscan2
- OR6C65 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as rs970262942, COSV101110188; called by muse, mutect2, varscan2
- OR6C74 | c.226A>T p.I76F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV59605979; called by mutect2, varscan2
- OR8B2 | c.672C>A p.S224R | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); catalogued as COSV100899333; called by muse, mutect2, varscan2
- PACS2 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100330782; called by muse, mutect2, varscan2
- PAK5 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV62020939; called by muse, mutect2, varscan2
- PARPBP | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as rs1402887343; called by muse, mutect2, varscan2
- PCDH10 | c.2854C>G p.R952G | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs144017898; called by muse, varscan2
- PCDH11X | c.2404G>C p.D802H | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV53507890; called by muse, mutect2, varscan2
- PCDHA2 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 76/567 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as rs782117441; called by muse, mutect2, varscan2
- PDE6B | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV55330699; called by muse, mutect2, varscan2
- PDE6B | c.1921-5C>T | Splice Region (SNP) | VAF 84/272 reads (31%) | catalogued as rs780649581; called by muse, mutect2, varscan2
- PKHD1L1 | c.5986G>T p.E1996* | Nonsense Mutation (SNP) | VAF 21/152 reads (14%) | catalogued as COSV99058815; called by muse, mutect2
- PLEKHG4B | c.26C>A p.P9H (on ENST00000283426; = p.P365H on NM_052909.5) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs778169333; called by muse, mutect2, varscan2
- PLPPR4 | c.2123T>C p.V708A | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as rs756715860; called by muse, mutect2, varscan2
- PLXNC1 | c.2174C>G p.S725* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as COSV51574967; called by muse, mutect2, varscan2
- POLD1 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.41); catalogued as rs555452657, COSV54532942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU3F2 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.473); catalogued as COSV100099008, COSV60409327; called by muse, mutect2, varscan2
- PPP1R16B | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55376127; called by muse, mutect2
- PRDM9 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.331); catalogued as rs757609204, COSV57011230; called by muse, mutect2, varscan2
- PTCHD4 | c.2371A>T p.T791S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV59781541; called by muse, mutect2, varscan2
- PTPRC | c.1511A>T p.K504M | Missense Mutation (SNP) | VAF 44/303 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV61408757; called by muse, mutect2, varscan2
- RBL2 | c.2347C>T p.Q783* | Nonsense Mutation (SNP) | VAF 27/261 reads (10%) | catalogued as COSV50881917; called by muse, mutect2, varscan2
- RGPD3 | c.3449A>T p.K1150I | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs745406735, COSV58740551; called by muse, mutect2, varscan2
- RGS8 | c.159G>T p.W53C (on ENST00000367556 / NM_001369564.2; = p.W71C on NM_033345.3) | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51120223; called by muse, mutect2, varscan2
- RNASE10 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs750509822; called by muse, mutect2, varscan2
- RNF150 | c.987G>A p.P329= | Splice Region (SNP) | VAF 37/134 reads (28%) | catalogued as COSV60791401; called by muse, varscan2
- SCNN1A | c.1737C>G p.I579M | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.768); catalogued as rs759899427, COSV99964742; called by muse, mutect2
- SCNN1D | c.1191C>G p.F397L (on ENST00000338555; = p.F561L on NM_001130413.4) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs924291622; called by muse, mutect2, varscan2
- SEMA5A | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 46/457 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766020101; called by muse, mutect2, varscan2
- SFT2D2 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV54799622; called by muse, mutect2
- SHLD1 | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV57435108; called by muse, mutect2, varscan2
- SIGLEC1 | c.4664G>A p.R1555Q | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as rs1426511275, COSV52472877; called by muse, mutect2, varscan2
- SIGLEC6 | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV58432615; called by muse, mutect2, varscan2
- SIRPA | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV100605143; called by muse, varscan2
- SKP2 | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs954965418; called by muse, mutect2, varscan2
- SLC30A10 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV63070405, COSV63074070; called by muse, mutect2, varscan2
- SMARCA4 | c.3713C>T p.S1238F | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60793955; called by muse, mutect2, varscan2
- SNX13 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1405242407; called by muse, varscan2
- SP110 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51254276; called by muse, varscan2
- SPTBN2 | c.6778G>T p.D2260Y | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456339071; called by muse, mutect2
- SSTR3 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1311437187, COSV100142941; called by muse, mutect2, varscan2
- STK11 | c.581del p.D194Afs*93 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as CM1413362, COSV58821130, COSV58822175; called by mutect2, pindel
- SYCP1 | c.1321-3T>C | Splice Region (SNP) | VAF 16/79 reads (20%) | catalogued as rs1054356795; called by muse, mutect2, varscan2
- SYT10 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 33/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57340141; called by muse, mutect2, varscan2
- SYT16 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 109/471 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1289497787; called by muse, mutect2, varscan2
- TAF1L | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 86/387 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV54257906; called by muse, mutect2, varscan2
- TARS1 | c.2120G>T p.R707L | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV54307570, COSV54311165; called by muse, mutect2, varscan2
- TCP11X2 | c.710-5C>T | Splice Region (SNP) | VAF 15/115 reads (13%) | catalogued as rs1324775029; called by mutect2, varscan2
- TENT2 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as COSV57139410; called by muse, mutect2, varscan2
- TEX15 | c.397G>T p.E133* (on ENST00000256246; = p.E516* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 31/125 reads (25%) | catalogued as COSV56354697; called by muse, mutect2, varscan2
- TKTL2 | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as COSV54919560, COSV99761686; called by muse, mutect2, varscan2
- TLL1 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs775028588; called by muse, mutect2, varscan2
- TMEM169 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.667); catalogued as COSV99824458; called by muse, mutect2, varscan2
- TMEM231 | c.46C>A p.R16S (on ENST00000258173 / NM_001077418.3; = p.T12= on NM_001077416.2) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1465828368; called by mutect2, varscan2
- TMPRSS11F | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100678287; called by muse, mutect2
- TNXB | c.2726C>T p.T909I | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs777338472; called by muse, mutect2, varscan2
- TRIO | c.7940A>G p.K2647R | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.874); catalogued as rs980405395; called by muse, mutect2, varscan2
- TTN | c.43813G>T p.E14605* (on ENST00000591111; = p.E7181* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV59873295; called by muse, mutect2
- UNC79 | c.7823G>A p.R2608Q (on ENST00000393151 / NM_001346218.2; = p.R2431Q on NM_020818.5) | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.448); catalogued as rs368890148; called by muse, mutect2, varscan2
- WDFY1 | c.620G>T p.W207L | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99239735; called by muse, varscan2
- XRN1 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs774268886; called by muse, varscan2
- ZIC4 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67173250; called by muse, mutect2, varscan2
- ZNF211 | c.538G>A p.V180M (on ENST00000347302 / NM_198855.4; = p.V193M on NM_006385.5) | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.526); catalogued as rs1210695731; called by muse, mutect2, varscan2
- ZNF490 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61008154; called by muse, mutect2, varscan2
- ZNF492 | c.128del p.P43Qfs*24 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs1357604127; called by mutect2, varscan2
- ZNF518B | c.2063A>T p.H688L | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV58722345; called by muse, mutect2
- ZNF716 | c.775C>A p.H259N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs781810479, COSV70782822; called by muse, mutect2, varscan2
- ZNF761 | c.1914A>T p.E638D | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV100483191; called by muse, mutect2, varscan2
- ZP4 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs988716758; called by muse, mutect2, varscan2
- ABCA12 | c.6234G>C p.G2078= (on ENST00000272895 / NM_173076.3; = p.G1760= on NM_015657.3) | Splice Region (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- ABCA3 | c.188A>T p.Q63L | Missense Mutation (SNP) | VAF 83/476 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCC11 | c.1655G>C p.S552T | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- AC013477.1 | c.2497C>T p.Q833* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- ACACB | c.6850G>T p.D2284Y | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ACTC1 | c.1030G>T p.G344W | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS19 | c.2546G>T p.W849L | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS9 | c.4905G>C p.R1635S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADD2 | c.2054A>T p.E685V | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADGRB1 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.011); called by muse, mutect2
- ADGRG3 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ADGRL3 | c.14A>T p.Q5L | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ADGRV1 | c.3829G>T p.V1277L | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2
- ADNP | c.2495_2525del p.N832Mfs*72 | Frame Shift Del (DEL) | VAF 28/272 reads (10%) | called by mutect2, pindel
- AFP | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK | c.12662G>T p.G4221V | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AIM2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- AKAP9 | c.5529G>C p.W1843C (on ENST00000359028; = p.W1811C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ALPG | c.1277C>A p.P426Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ALPP | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 57/586 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); called by muse, mutect2
- AMPD2 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- ANGPT1 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOA2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.013); called by muse, mutect2
- APOB | c.11515G>C p.D3839H | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ARHGAP15 | c.1071G>T p.M357I | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ARMC9 | c.2024C>A p.T675K | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- ASIC1 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ASXL3 | c.6103C>T p.P2035S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ATG2B | c.6118G>T p.V2040L | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ATR | c.4642-1G>C p.X1548_splice | Splice Site (SNP) | VAF 29/177 reads (16%) | called by muse, mutect2, varscan2
- ATRN | c.3825T>A p.N1275K | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.027); called by muse, mutect2
- ATXN1 | c.281G>T p.R94M | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- AVIL | c.470T>G p.F157C | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AVL9 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); called by muse, mutect2
- AXDND1 | c.1289G>T p.W430L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); called by muse, mutect2
- BLOC1S1 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- BMP4 | c.974G>T p.W325L | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- BNC1 | c.351T>A p.S117R | Missense Mutation (SNP) | VAF 141/503 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C16orf78 | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C16orf82 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- C5orf34 | c.352A>T p.M118L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C5orf51 | c.166_167del p.E56Mfs*22 | Frame Shift Del (DEL) | VAF 25/173 reads (14%) | called by mutect2, pindel, varscan2
- CACNA1B | c.5001C>A p.N1667K | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CACNA1C | c.5233C>A p.H1745N | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CALHM4 | c.683A>T p.E228V (on ENST00000368596 / NM_001366078.1; = p.E42V on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CARMIL1 | c.3370G>C p.E1124Q | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CATSPER3 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CD1D | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CD248 | c.965G>T p.C322F | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD36 | c.1006+2T>A p.X336_splice | Splice Site (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- CD8B | c.507C>A p.S169R | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- CDH11 | c.2299T>A p.L767M | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- CDH23 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- CELF2 | c.757-2A>T p.X253_splice (on ENST00000416382 / NM_001025077.3; = p.X260_splice on NM_006561.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 34/193 reads (18%) | called by muse, mutect2, varscan2
- CEP112 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 14/167 reads (8%) | called by muse, mutect2
- CEP97 | c.1371G>T p.W457C | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- CFAP46 | c.6537-2A>G p.X2179_splice | Splice Site (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- CIDEC | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.368); called by muse, mutect2
- CILP | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 131/358 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CKAP5 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- CNGB3 | c.1951A>C p.K651Q | Missense Mutation (SNP) | VAF 77/353 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CNKSR2 | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CNOT1 | c.5499T>A p.H1833Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2
- COL11A1 | c.4994A>T p.K1665M | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL15A1 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL18A1 | c.3644G>T p.G1215V (on ENST00000359759 / NM_130444.3; = p.G980V on NM_030582.4) | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A1 | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 71/256 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COX11 | c.212C>G p.P71R | Missense Mutation (SNP) | VAF 85/392 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPNE5 | c.1032G>T p.Q344H | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CREB5 | c.1136G>T p.R379L (on ENST00000357727 / NM_182898.4; = p.R372L on NM_004904.3) | Missense Mutation (SNP) | VAF 59/379 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CRISP3 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); called by muse, varscan2
- CRYBG2 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); called by muse, mutect2
- CSMD3 | c.1430G>A p.G477E (on ENST00000297405 / NM_001363185.1; = p.G373E on NM_052900.3) | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CSN2 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 32/162 reads (20%) | called by muse, mutect2, varscan2
- CSNK2A1 | c.1114G>C p.V372L | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- CTNNB1 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CYP11B2 | c.206A>T p.H69L | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CYP26C1 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAB1 | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); called by muse, mutect2
- DAB2 | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DCAF4L2 | c.1147A>T p.M383L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DEFB127 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DEPTOR | c.116A>T p.Q39L | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2
- DIXDC1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2
- DLG2 | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, varscan2
- DMD | c.9136G>A p.G3046S | Missense Mutation (SNP) | VAF 87/270 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMRTB1 | c.878A>G p.H293R | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, varscan2
- DNAH12 | c.5109A>T p.E1703D (on ENST00000351747; = p.E1726D on NM_001366028.2) | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC6 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNMBP | c.2626G>C p.A876P | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DOCK6 | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DPP4 | c.405T>A p.Y135* | Nonsense Mutation (SNP) | VAF 34/118 reads (29%) | called by muse, varscan2
- DPPA4 | c.476A>G p.Q159R | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DSCAML1 | c.3871C>A p.P1291T (on ENST00000321322; = p.P1231T on NM_020693.4) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); called by muse, varscan2
- EBF4 | c.240del p.Q81Sfs*120 (on ENST00000609451; = p.Q77Sfs*120 on NM_001110514.1) | Frame Shift Del (DEL) | VAF 22/144 reads (15%) | called by mutect2, pindel, varscan2
- EDEM3 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EFEMP1 | c.183T>G p.C61W | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EFS | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- ELAVL2 | c.918G>T p.K306N | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); called by muse, varscan2
- ELAVL4 | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ELFN1 | c.2157dup p.G720Rfs*270 | Frame Shift Ins (INS) | VAF 41/185 reads (22%) | called by mutect2, pindel, varscan2
- ELOA | c.1046_1047delinsG p.N349Sfs*3 | Frame Shift Del (DEL) | VAF 72/281 reads (26%) | called by pindel, varscan2*
- EMILIN1 | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENPEP | c.622T>A p.Y208N | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ENPEP | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ENTR1 | c.987G>C p.Q329H (on ENST00000357365 / NM_001039707.2; = p.Q306H on NM_006643.4) | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2
- EPG5 | c.7036G>T p.G2346* | Nonsense Mutation (SNP) | VAF 50/217 reads (23%) | called by muse, mutect2, varscan2
- EPHA4 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM102A | c.805G>T p.G269W (on ENST00000373095 / NM_001035254.3; = p.G127W on NM_203305.2) | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FAM110B | c.305del p.G102Afs*15 | Frame Shift Del (DEL) | VAF 53/274 reads (19%) | called by mutect2, pindel, varscan2
- FAM135B | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- FAM32A | c.204G>T p.M68I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM47B | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT3 | c.13463G>T p.S4488I | Missense Mutation (SNP) | VAF 94/368 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- FER1L5 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF5 | c.783C>A p.Y261* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | called by muse, varscan2
- FHL1 | c.619T>A p.Y207N | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- FLG | c.10363G>C p.D3455H | Missense Mutation (SNP) | VAF 86/437 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLG | c.10081G>A p.A3361T | Missense Mutation (SNP) | VAF 94/510 reads (18%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FREM2 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 36/287 reads (13%) | called by muse, mutect2, varscan2
- FSIP1 | c.413A>T p.E138V | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2
- FST | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- FSTL5 | c.964T>A p.Y322N | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- GABPB2 | c.823A>C p.I275L | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- GABRA2 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALC | c.1463G>T p.S488I | Missense Mutation (SNP) | VAF 48/461 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GARNL3 | c.2437G>T p.G813* | Nonsense Mutation (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2, varscan2
- GARRE1 | c.1112T>C p.M371T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GDF6 | c.1169C>G p.P390R | Missense Mutation (SNP) | VAF 170/679 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GFAP | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.017); called by muse, mutect2
- GJA4 | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GKN2 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.357); called by muse, mutect2
- GLDN | c.853G>T p.V285F | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- GLDN | c.991A>T p.S331C | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- GPAT4 | c.923A>T p.H308L | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- GPNMB | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, varscan2
- GPR183 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRB10 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- GREB1L | c.2601G>C p.E867D | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GRIK2 | c.266T>A p.F89Y | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); called by muse, mutect2
- GZMM | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- HDAC9 | c.2795-1G>T p.X932_splice | Splice Site (SNP) | VAF 26/106 reads (25%) | called by muse, varscan2
- HDGFL2 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- HECW2 | c.2599C>A p.R867S | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- HEPACAM2 | c.1163G>T p.R388M (on ENST00000394468 / NM_001039372.4; = p.R376M on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HEPHL1 | c.502G>C p.V168L | Missense Mutation (SNP) | VAF 92/415 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- HRH3 | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- HTR3A | c.168G>T p.R56S | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ICE1 | c.3986G>T p.G1329V | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ICE1 | c.5593G>T p.E1865* | Nonsense Mutation (SNP) | VAF 30/147 reads (20%) | called by muse, mutect2, varscan2
- IFI44L | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- IL17RA | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 74/348 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IL21 | c.280A>T p.R94W | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- INTS11 | c.746G>C p.C249S | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); called by muse, mutect2
- IRF4 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- IRX4 | c.350C>G p.P117R | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ISG15 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ITSN2 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- KCNH7 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 56/231 reads (24%) | called by muse, mutect2, varscan2
- KCNU1 | c.2715C>G p.F905L | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- KDM5A | c.2318G>T p.R773M | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- KIAA1328 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIR2DL1 | c.1043C>A p.P348Q | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLRG1 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- KRT1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- KRT2 | c.921C>A p.N307K | Missense Mutation (SNP) | VAF 46/455 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2
- KRT76 | c.1216A>T p.R406W | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP12-3 | c.229del p.Q77Sfs*? | Frame Shift Del (DEL) | VAF 34/168 reads (20%) | called by mutect2, pindel, varscan2
- LAIR1 | c.718-1G>A p.X240_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- LAIR1 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 91/282 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LHX9 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2
- LIFR | c.1725T>G p.C575W | Missense Mutation (SNP) | VAF 43/328 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LIFR | c.1724G>T p.C575F | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LILRA4 | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LIPG | c.459+4C>G | Splice Region (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- LNPK | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LNPK | c.835T>G p.C279G | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.10183G>T p.V3395F | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- LRP2 | c.9118C>A p.Q3040K | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LRRC53 | c.1319T>A p.L440* | Nonsense Mutation (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- LRRC63 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- LRRC7 | c.2767C>A p.P923T (on ENST00000651989 / NM_001370785.2; = p.P890T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LTB | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- LTBP2 | c.2053C>A p.L685M | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- MACC1 | c.1672A>T p.K558* | Nonsense Mutation (SNP) | VAF 25/169 reads (15%) | called by muse, mutect2, varscan2
- MAGEL2 | c.941C>A p.P314Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MAJIN | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MALRD1 | c.4828A>T p.I1610F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2
- MAML2 | c.2909A>G p.E970G | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2
- MANBA | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- MAPK8IP3 | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MASP1 | c.1229-1G>T p.X410_splice | Splice Site (SNP) | VAF 62/305 reads (20%) | called by muse, mutect2, varscan2
- MBTPS1 | c.685A>T p.K229* | Nonsense Mutation (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- MBTPS2 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MEP1B | c.1653T>A p.F551L | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.582); called by muse, mutect2
- MICAL3 | c.4163G>T p.R1388M | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- MICU2 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, varscan2
- MLF2 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MRC1 | c.1795G>T p.G599W | Missense Mutation (SNP) | VAF 68/395 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC2 | c.787T>A p.W263R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MROH1 | c.1786G>C p.E596Q | Missense Mutation (SNP) | VAF 23/261 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2
- MTHFR | c.586+1G>A p.X196_splice | Splice Site (SNP) | VAF 48/438 reads (11%) | called by muse, mutect2, varscan2
- MXRA5 | c.755T>A p.L252* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2
- MYH1 | c.2072A>T p.E691V | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYH6 | c.4179del p.K1394Sfs*34 | Frame Shift Del (DEL) | VAF 57/326 reads (17%) | called by mutect2, pindel, varscan2
- MYH8 | c.1588-1G>T p.X530_splice | Splice Site (SNP) | VAF 38/168 reads (23%) | called by muse, mutect2, varscan2
- MYO9B | c.3725G>T p.S1242I | Missense Mutation (SNP) | VAF 45/441 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- NALCN | c.3423C>A p.F1141L | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); called by muse, mutect2
- NAT10 | c.733A>C p.T245P | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- NAT16 | c.209C>G p.S70W | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- NCOA2 | c.4083G>T p.M1361I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- NKX1-1 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- NLGN1 | c.2243A>T p.H748L | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.055); called by muse, mutect2
- NLRP4 | c.2303C>A p.P768H | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- NRAP | c.1162T>C p.C388R | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NXPE2 | c.727C>A p.Q243K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OPRM1 | c.787A>T p.S263C | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR10C1 | c.64G>T p.A22S (on ENST00000622521; = p.A20S on NM_013941.3) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- OR10W1 | c.213T>A p.H71Q | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR13A1 | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 25/322 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR1L8 | c.398A>T p.Y133F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR2H1 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- OR2V2 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OR5AN1 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5K2 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACSIN2 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- PAK5 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 34/370 reads (9%) | called by muse, mutect2
- PAPSS2 | c.111G>T p.R37S | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCBP1 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.055); called by muse, mutect2
- PCDH11Y | c.3274C>T p.R1092C | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PCDH15 | c.842C>A p.T281N | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCDHA6 | c.584T>C p.L195S | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PCDHB16 | c.1979T>A p.V660E | Missense Mutation (SNP) | VAF 39/385 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PCDHB8 | c.2345C>A p.P782Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- PCDHGA11 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.175); called by muse, mutect2
- PEX1 | c.2815T>C p.F939L | Missense Mutation (SNP) | VAF 34/610 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- PGBD2 | c.1221G>T p.E407D | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHKA1 | c.3415G>C p.D1139H | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PHKA2 | c.2343C>G p.Y781* | Nonsense Mutation (SNP) | VAF 45/136 reads (33%) | called by muse, mutect2, varscan2
- PHLDA1 | c.304del p.A102Qfs*50 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- PIK3CB | c.1377A>T p.L459F | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEC | c.116A>T p.H39L | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PLEKHD1 | c.465G>C p.Q155H | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLIN3 | c.1187G>T p.S396I | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- POF1B | c.1546C>A p.L516I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- POP1 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 71/518 reads (14%) | called by muse, mutect2, varscan2
- POU5F2 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PPFIA1 | c.2163+1G>T p.X721_splice | Splice Site (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- PRDM9 | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 83/402 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCB | c.1867G>C p.D623H | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.029); called by muse, mutect2
- PRMT1 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.824); called by muse, mutect2
- PRRC2C | c.314A>G p.Q105R (on ENST00000367742; = p.Q103R on NM_015172.4) | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- PTGS1 | c.300G>C p.E100D | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- PXDN | c.4301G>A p.C1434Y | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAB37 | c.246+1G>T p.X82_splice (on ENST00000392613 / NM_001006638.3; = p.X75_splice on NM_175738.5) | Splice Site (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- RABEP1 | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- RBFOX2 | c.896C>T p.S299F (on ENST00000438146 / NM_001349995.2; = p.S229F on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- RGPD3 | c.3526C>T p.L1176F | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- RGPD4 | c.2804A>G p.K935R | Missense Mutation (SNP) | VAF 49/420 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- RNF216 | c.2425del p.L809Cfs*92 (on ENST00000425013 / NM_207116.3; = p.L866Cfs*92 on NM_207111.4) | Frame Shift Del (DEL) | VAF 20/138 reads (14%) | called by pindel, varscan2
- ROBO4 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RPGR | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.085); called by muse, varscan2
- RPUSD4 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2
- RREB1 | c.4049G>T p.G1350V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- RTEL1 | c.2074A>C p.N692H | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTL3 | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- RTN1 | c.1993A>C p.I665L | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- SATL1 | c.1318C>G p.L440V (on ENST00000395409; = p.L627V on NM_001367857.2) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SBF1 | c.2823G>T p.M941I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SBNO2 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC16B | c.3111G>T p.Q1037H | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEC23A | c.1903G>T p.V635F | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINA9 | c.1120T>A p.F374I | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SERPINB3 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SETBP1 | c.4562C>G p.P1521R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SETX | c.3152C>T p.S1051L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- SGCD | c.724C>A p.L242I (on ENST00000435422 / NM_001128209.2; = p.L243I on NM_000337.5) | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SHISAL2A | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SHROOM2 | c.3935A>C p.E1312A | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SIRPG | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, varscan2
- SLC12A5 | c.2647A>T p.T883S (on ENST00000454036 / NM_001134771.2; = p.T860S on NM_020708.5) | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SLC12A7 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLC18A3 | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC29A1 | c.695A>T p.Y232F | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLC30A10 | c.1253G>C p.G418A | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLC30A10 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- SLC37A3 | c.358T>G p.C120G | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- SLC38A8 | c.1029dup p.L344Afs*24 | Frame Shift Ins (INS) | VAF 27/252 reads (11%) | called by mutect2, pindel, varscan2
- SLC43A1 | c.578T>A p.V193E | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC4A11 | c.596A>C p.Q199P | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- SLC6A17 | c.293A>C p.Y98S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC6A7 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9C1 | c.1962_1963del p.I656Sfs*6 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- SLIT2 | c.2073_2074insA p.Q692Tfs*22 | Frame Shift Ins (INS) | VAF 41/201 reads (20%) | called by mutect2, pindel*, varscan2
- SLTM | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.439); called by muse, mutect2
- SNAP91 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); called by muse, mutect2
- SOGA1 | c.3282G>T p.Q1094H | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- SOX7 | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- SPINK5 | c.2586C>G p.I862M | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2
- SPTSSB | c.44A>T p.Y15F | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.04); called by muse, mutect2
- SRCAP | c.6049del p.R2017Gfs*19 | Frame Shift Del (DEL) | VAF 43/332 reads (13%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2140G>A p.E714K (on ENST00000621492; = p.E680K on NM_025248.3) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- STARD3 | c.366G>T p.W122C | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- STX11 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- STYXL2 | c.912G>T p.M304I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SYNE3 | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.134); called by muse, mutect2
- TACC1 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TEP1 | c.5632G>T p.A1878S | Missense Mutation (SNP) | VAF 67/477 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TEX13C | c.1905dup p.V636Sfs*35 | Frame Shift Ins (INS) | VAF 69/233 reads (30%) | called by pindel, varscan2
- TKTL1 | c.1317+1G>T p.X439_splice | Splice Site (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- TM4SF4 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- TMC3 | c.3122C>A p.S1041Y | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMCO4 | c.898G>C p.A300P | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- TMEM132A | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM239 | c.377C>T p.T126I (on ENST00000361033 / NM_001318207.1; = p.T83I on NM_001167670.3) | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- TRBV28 | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | called by muse, mutect2, varscan2
- TRIM38 | c.845A>T p.D282V | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- TRIM51GP | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.089); called by muse, mutect2
- TRIM55 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2
- TRPM1 | c.3015G>T p.M1005I | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- TTN | c.87581A>C p.K29194T (on ENST00000591111; = p.K21770T on NM_003319.4) | Missense Mutation (SNP) | VAF 90/352 reads (26%) | PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TTN | c.53845G>C p.E17949Q (on ENST00000591111; = p.E10525Q on NM_003319.4) | Missense Mutation (SNP) | VAF 48/209 reads (23%) | PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- TTN | c.47489C>T p.P15830L (on ENST00000591111; = p.P8406L on NM_003319.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TYMP | c.851C>A p.A284D | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2
- UBTFL1 | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UGT1A10 | c.409T>A p.L137I | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- UMOD | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 18/342 reads (5%) | called by muse, mutect2
- UNC13A | c.1519-1G>T p.X507_splice | Splice Site (SNP) | VAF 49/219 reads (22%) | called by muse, mutect2, varscan2
- USH1G | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, mutect2
- USH2A | c.8392G>T p.G2798W | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- USP29 | c.2284G>T p.E762* | Nonsense Mutation (SNP) | VAF 47/152 reads (31%) | called by muse, mutect2, varscan2
- USP32 | c.3902T>A p.F1301Y | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- VGLL3 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.383); called by muse, varscan2
- VPS13C | c.10178A>T p.K3393M (on ENST00000644861 / NM_020821.3; = p.K3350M on NM_017684.5) | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, varscan2
- VPS50 | c.2442A>G p.I814M | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VSIR | c.463C>G p.H155D | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- WDR17 | c.3114G>C p.L1038F | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- WSCD1 | c.935G>T p.S312I | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- XIRP2 | c.1229C>G p.P410R (on ENST00000628543; = p.P585R on NM_152381.6) | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBED2 | c.130A>T p.T44S | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB42 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZDBF2 | c.246G>T p.L82F | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX2 | c.684_686del p.S228_G229delinsR | In Frame Del (DEL) | VAF 20/176 reads (11%) | called by mutect2, pindel
- ZNF175 | c.2085_2105del p.R695_C701del | In Frame Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- ZNF180 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF280A | c.1282T>C p.C428R | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF329 | c.1225A>T p.I409F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2
- ZNF335 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); called by muse, mutect2
- ZNF407 | c.5918T>C p.L1973S | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF438 | c.1722A>T p.K574N | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF460 | c.104G>T p.R35M | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF469 | c.1777C>A p.L593M | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF480 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF521 | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- ZNF521 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2
- ZNF691 | c.368C>A p.T123N (on ENST00000372502; = p.T92N on NM_015911.3) | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- ZNF729 | c.2775A>T p.K925N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ZNF841 | c.1007C>G p.T336S (on ENST00000426391 / NM_001369830.1; = p.T452S on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ZSWIM2 | c.403T>A p.Y135N | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ABCA4 | c.2028G>A p.L676= | Silent (SNP) | VAF 69/337 reads (20%) | called by muse, mutect2, varscan2
- ABHD10 | c.273A>G p.T91= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, varscan2
- ABI3BP | c.2526G>T p.V842= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- AC134980.2 | c.759T>A p.P253= | Silent (SNP) | VAF 20/137 reads (15%) | called by muse, varscan2
- ACP4 | c.195A>T p.R65= | Silent (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- ADGRA1 | c.1494G>A p.T498= | Silent (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- ADGRG1 | c.1596G>C p.T532= | Silent (SNP) | VAF 38/395 reads (10%) | called by muse, mutect2, varscan2
- AGTR1 | c.150G>T p.V50= | Silent (SNP) | VAF 44/262 reads (17%) | catalogued as COSV100837105; called by muse, mutect2, varscan2
- AKAP9 | c.9394C>T p.L3132= (on ENST00000359028; = p.L3108= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/151 reads (54%) | catalogued as COSV100662107; called by muse, mutect2, varscan2
- ALDH16A1 | c.1710G>T p.V570= | Silent (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- AMIGO2 | c.723C>G p.V241= | Silent (SNP) | VAF 42/289 reads (15%) | called by muse, mutect2, varscan2
- ANKDD1A | c.1392C>G p.L464= | Silent (SNP) | VAF 82/197 reads (42%) | called by muse, mutect2, varscan2
- AOAH | c.186C>A p.V62= | Silent (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.1554G>T p.V518= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- ARHGAP4 | c.882C>G p.T294= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- B4GALNT3 | c.1737G>A p.R579= | Silent (SNP) | VAF 33/331 reads (10%) | catalogued as COSV56758273; called by muse, mutect2, varscan2
- BAZ2A | c.3387G>T p.P1129= | Silent (SNP) | VAF 26/144 reads (18%) | called by muse, varscan2
- BMPR1B | c.886C>T p.L296= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs769195694; called by muse, mutect2, varscan2
- BSND | c.951C>T p.D317= | Silent (SNP) | VAF 25/294 reads (9%) | catalogued as rs876657432; called by muse, mutect2
- C15orf61 | c.174C>T p.V58= | Silent (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- C8orf48 | c.213T>C p.S71= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- CA10 | c.327G>T p.L109= | Silent (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- CAMK2N1 | c.33G>A p.K11= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- CBLN4 | c.48G>A p.L16= | Silent (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- CCDC80 | c.1362C>T p.S454= | Silent (SNP) | VAF 20/311 reads (6%) | called by muse, mutect2
- CCN6 | c.258C>T p.C86= | Silent (SNP) | VAF 45/253 reads (18%) | catalogued as rs1194134735; called by muse, mutect2, varscan2
- CD300LF | c.807C>A p.L269= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as COSV56899523; called by muse, mutect2
- CELF4 | c.651C>T p.T217= | Silent (SNP) | VAF 36/172 reads (21%) | catalogued as COSV58458110; called by muse, mutect2, varscan2
- CHL1 | c.690C>A p.I230= (on ENST00000397491 / NM_001253387.1; = p.I246= on NM_006614.4) | Silent (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- CHRNG | c.768C>G p.S256= | Silent (SNP) | VAF 30/304 reads (10%) | catalogued as COSV67315621, COSV67315972; called by muse, mutect2, varscan2
- CNR1 | c.1131G>T p.T377= | Silent (SNP) | VAF 38/243 reads (16%) | catalogued as rs202070651; called by muse, mutect2, varscan2
- CNTNAP5 | c.3585G>A p.T1195= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs368921834, COSV70470217; called by muse, varscan2
- COL18A1 | c.2883G>A p.E961= (on ENST00000359759 / NM_130444.3; = p.E726= on NM_030582.4) | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as rs771625222; called by muse, mutect2, varscan2
- COL9A1 | c.2403C>A p.P801= | Silent (SNP) | VAF 31/201 reads (15%) | catalogued as COSV57880373; called by muse, mutect2, varscan2
- CPSF7 | c.1215C>G p.A405= (on ENST00000394888 / NM_001136040.4; = p.A448= on NM_024811.4) | Silent (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- CPXM1 | c.321C>T p.P107= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs778212914; called by muse, mutect2, varscan2
- CSF3R | c.2451C>T p.L817= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs374780980, COSV100117645; called by muse, mutect2, varscan2
- CUEDC1 | c.969C>A p.A323= | Silent (SNP) | VAF 44/323 reads (14%) | called by muse, mutect2, varscan2
- DDC | c.921G>T p.V307= | Silent (SNP) | VAF 126/550 reads (23%) | called by muse, mutect2, varscan2
- DMD | c.7092C>T p.D2364= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs768559703; ClinVar: likely benign; called by muse, varscan2
- ENPEP | c.621C>T p.T207= | Silent (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- EVPL | c.252C>T p.G84= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- FAM135B | c.2484C>A p.P828= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV99425274; called by muse, mutect2, varscan2
- FAM214A | c.507T>C p.A169= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- FLG | c.6786T>A p.S2262= | Silent (SNP) | VAF 44/376 reads (12%) | called by muse, varscan2
- FOXP1 | c.678A>G p.T226= | Silent (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- FREM3 | c.1362C>A p.T454= | Silent (SNP) | VAF 31/173 reads (18%) | called by muse, mutect2, varscan2
- GABRG2 | c.222G>A p.L74= | Silent (SNP) | VAF 26/243 reads (11%) | catalogued as rs1433283612; called by muse, mutect2, varscan2
- GDAP2 | c.87C>G p.S29= | Silent (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- GDI2 | c.1236A>C p.T412= | Silent (SNP) | VAF 25/218 reads (11%) | called by muse, mutect2, varscan2
- GPR25 | c.933C>T p.D311= | Silent (SNP) | VAF 39/211 reads (18%) | called by muse, mutect2, varscan2
- GPR37 | c.534T>C p.D178= | Silent (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- GPR78 | c.486C>A p.P162= | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- GRID2IP | c.3441C>T p.D1147= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs572200460, COSV101474863; called by muse, mutect2, varscan2
- GRM7 | c.1812C>A p.A604= | Silent (SNP) | VAF 42/127 reads (33%) | called by muse, mutect2, varscan2
- HDHD5 | c.1161G>T p.G387= (on ENST00000336737 / NM_033070.3; = p.G357= on NM_017829.5) | Silent (SNP) | VAF 23/229 reads (10%) | called by muse, mutect2, varscan2
- HECTD4 | c.8412G>T p.L2804= | Silent (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- HELZ | c.5223G>T p.S1741= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100698704; called by muse, mutect2, varscan2
- HSD3B1 | c.561C>A p.P187= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as COSV52490373; called by muse, mutect2
- IGF2BP2 | c.462C>T p.Y154= | Silent (SNP) | VAF 26/425 reads (6%) | called by muse, mutect2
- IGHV3OR16-9 | c.216G>A p.R72= | Silent (SNP) | VAF 45/286 reads (16%) | catalogued as rs763167745, COSV61211392; called by muse, mutect2, varscan2
- IRAK2 | c.201G>T p.R67= | Silent (SNP) | VAF 32/126 reads (25%) | called by muse, mutect2, varscan2
- ITGA1 | c.222C>T p.N74= | Silent (SNP) | VAF 28/292 reads (10%) | called by muse, mutect2
- ITM2A | c.309A>T p.G103= | Silent (SNP) | VAF 48/159 reads (30%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2313C>A p.T771= (on ENST00000359125 / NM_172107.4; = p.T743= on NM_004518.6) | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, varscan2
- KDM2B | c.837G>A p.L279= | Silent (SNP) | VAF 53/181 reads (29%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.861G>A p.A287= | Silent (SNP) | VAF 13/152 reads (9%) | catalogued as rs373805813; called by muse, mutect2
- KRT20 | c.265C>A p.R89= | Silent (SNP) | VAF 53/290 reads (18%) | called by muse, mutect2, varscan2
- KRT6B | c.1386C>T p.I462= | Silent (SNP) | VAF 34/438 reads (8%) | catalogued as rs767159401, COSV52882148, COSV52884775; ClinVar: likely benign; called by muse, mutect2
- KTN1 | c.3201T>G p.A1067= (on ENST00000395314 / NM_001271014.2; = p.A1038= on NM_004986.4) | Silent (SNP) | VAF 41/199 reads (21%) | called by muse, mutect2, varscan2
- LAYN | c.363C>T p.C121= (on ENST00000375615 / NM_001258390.1; = p.C113= on NM_178834.5) | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV65104791; called by muse, mutect2, varscan2
- LILRA4 | c.258A>T p.P86= | Silent (SNP) | VAF 68/230 reads (30%) | called by muse, mutect2, varscan2
- LMTK3 | c.2670G>A p.A890= | Silent (SNP) | VAF 24/305 reads (8%) | catalogued as rs1309911534; called by muse, mutect2
- LRP1B | c.12696A>G p.K4232= | Silent (SNP) | VAF 37/171 reads (22%) | called by muse, varscan2
- LRRC24 | c.219C>A p.L73= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs1277427461; called by muse, mutect2, varscan2
- LRRC53 | c.1317C>A p.G439= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- LYPD1 | c.21G>A p.A7= | Silent (SNP) | VAF 15/214 reads (7%) | catalogued as rs774039435, COSV100494878; called by muse, mutect2
- MAGEA12 | c.255G>A p.E85= | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.606G>A p.P202= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs771836602; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1770C>T p.T590= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as rs775229551; called by muse, mutect2
- MDN1 | c.1185C>A p.G395= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs1251564412; called by muse, mutect2
- MEX3A | c.1041G>A p.V347= | Silent (SNP) | VAF 26/357 reads (7%) | called by muse, mutect2
- MME | c.621T>A p.T207= | Silent (SNP) | VAF 14/123 reads (11%) | called by muse, varscan2
- MON2 | c.3063G>A p.L1021= | Silent (SNP) | VAF 48/398 reads (12%) | called by muse, mutect2, varscan2
- MRC1 | c.168G>A p.Q56= | Silent (SNP) | VAF 30/664 reads (5%) | catalogued as COSV58889938; called by muse, mutect2
- MUC4 | c.2748C>T p.S916= | Silent (SNP) | VAF 24/376 reads (6%) | called by muse, mutect2
- MXRA5 | c.6379C>T p.L2127= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54250732; called by muse, mutect2, varscan2
- MYBPH | c.1059C>T p.T353= | Silent (SNP) | VAF 20/223 reads (9%) | catalogued as rs200996994, COSV99704471; called by muse, mutect2
- MYO3A | c.939C>A p.G313= | Silent (SNP) | VAF 48/308 reads (16%) | called by muse, varscan2
- NAT8L | c.442C>T p.L148= | Silent (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- NCF4 | c.588G>C p.V196= | Silent (SNP) | VAF 47/590 reads (8%) | catalogued as COSV50621203; called by muse, mutect2
- NELL1 | c.1245T>A p.T415= | Silent (SNP) | VAF 33/162 reads (20%) | called by muse, mutect2, varscan2
- NFS1 | c.27G>A p.R9= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV53615510; called by muse, varscan2
- NIPBL | c.6708C>T p.N2236= | Silent (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- NOBOX | c.606C>A p.A202= | Silent (SNP) | VAF 58/248 reads (23%) | called by muse, mutect2, varscan2
- NUP155 | c.537C>T p.S179= (on ENST00000231498 / NM_153485.3; = p.S120= on NM_004298.4) | Silent (SNP) | VAF 26/366 reads (7%) | called by muse, mutect2
- OAZ3 | c.48C>T p.I16= | Silent (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- OR1I1 | c.666C>T p.F222= | Silent (SNP) | VAF 52/224 reads (23%) | called by muse, mutect2, varscan2
- OR2K2 | c.459G>T p.V153= (on ENST00000374428; = p.V124= on NM_205859.2) | Silent (SNP) | VAF 23/263 reads (9%) | called by muse, mutect2
- OR5A2 | c.375T>A p.A125= | Silent (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- OR5D16 | c.228C>T p.S76= | Silent (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- OR5I1 | c.177C>A p.T59= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as rs750061398, COSV56885342; called by muse, mutect2, varscan2
- PAPPA2 | c.1272C>A p.G424= | Silent (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- PCDH10 | c.3066G>T p.L1022= | Silent (SNP) | VAF 18/96 reads (19%) | called by muse, varscan2
- PCDHA7 | c.471G>T p.A157= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as COSV65343940; called by muse, mutect2
- PCDHB15 | c.120G>A p.E40= | Silent (SNP) | VAF 31/254 reads (12%) | catalogued as rs207466432, COSV50861306, COSV51373375; called by muse, mutect2, varscan2
- PCDHGA11 | c.447T>C p.P149= | Silent (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2
- PDE2A | c.2214C>A p.L738= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- PIEZO2 | c.3241C>A p.R1081= | Silent (SNP) | VAF 58/250 reads (23%) | catalogued as COSV57450581; called by muse, varscan2
- PKP2 | c.486G>T p.T162= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs189040311; called by muse, mutect2, varscan2
- PLXNA4 | c.705C>A p.T235= | Silent (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- PLXND1 | c.4342C>T p.L1448= | Silent (SNP) | VAF 27/145 reads (19%) | called by muse, mutect2, varscan2
- PNLIP | c.681C>A p.V227= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- PNMA1 | c.882C>T p.V294= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs1409110389; called by muse, mutect2
- PPEF1 | c.114A>G p.Q38= | Silent (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- PRDM9 | c.1353C>A p.T451= | Silent (SNP) | VAF 24/488 reads (5%) | called by muse, mutect2
- PTGDS | c.219G>T p.T73= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV56399782; called by muse, mutect2, varscan2
- PTPRJ | c.3738G>T p.T1246= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV101395041; called by muse, mutect2, varscan2
- PXDNL | c.2400G>A p.T800= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100683264, COSV100683600; called by muse, mutect2, varscan2
- ROBO3 | c.2745C>T p.R915= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- RTN1 | c.117G>C p.T39= | Silent (SNP) | VAF 21/177 reads (12%) | catalogued as rs1454001429; called by muse, mutect2, varscan2
- SALL3 | c.3204C>T p.H1068= | Silent (SNP) | VAF 27/168 reads (16%) | catalogued as rs1449581834; called by muse, mutect2, varscan2
- SERPINB5 | c.1077G>A p.R359= | Silent (SNP) | VAF 26/159 reads (16%) | called by muse, mutect2, varscan2
- SHPK | c.15G>T p.P5= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV50441353; called by muse, mutect2, varscan2
- SHROOM4 | c.1776G>T p.L592= | Silent (SNP) | VAF 53/176 reads (30%) | called by muse, mutect2, varscan2
- SHROOM4 | c.729C>A p.T243= | Silent (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.639C>G p.A213= | Silent (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2, varscan2
- SPATA16 | c.420A>G p.V140= | Silent (SNP) | VAF 57/382 reads (15%) | catalogued as rs751905415; called by muse, mutect2, varscan2
- SPTBN4 | c.3165G>A p.Q1055= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as rs966782255, COSV58954421; called by muse, mutect2
- SRSF3 | c.180T>G p.A60= | Silent (SNP) | VAF 59/260 reads (23%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.933G>A p.A311= | Silent (SNP) | VAF 16/193 reads (8%) | catalogued as rs745413528, COSV99185086, COSV99185421; called by muse, mutect2
- SYNE1 | c.26098C>A p.R8700= (on ENST00000367255 / NM_182961.4; = p.R8652= on NM_033071.3) | Silent (SNP) | VAF 38/170 reads (22%) | called by muse, mutect2, varscan2
- TAF13 | c.273A>T p.R91= | Silent (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- TAS1R2 | c.573C>T p.I191= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs766449123; called by muse, mutect2, varscan2
- TBC1D30 | c.501C>T p.I167= | Silent (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- TIAM1 | c.2716C>T p.L906= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as COSV54536388; called by muse, mutect2, varscan2
- TMEM130 | c.636G>A p.A212= | Silent (SNP) | VAF 13/233 reads (6%) | catalogued as rs917628738, COSV100229072; called by muse, mutect2
- TMEM132B | c.1806G>T p.V602= | Silent (SNP) | VAF 81/308 reads (26%) | called by muse, mutect2, varscan2
- TNR | c.2511C>T p.A837= | Silent (SNP) | VAF 31/167 reads (19%) | called by muse, mutect2, varscan2
- TOB1 | c.69A>G p.R23= | Silent (SNP) | VAF 13/128 reads (10%) | called by muse, varscan2
- TSGA10 | c.816C>T p.C272= | Silent (SNP) | VAF 38/186 reads (20%) | called by muse, mutect2, varscan2
- TSNAXIP1 | c.1308C>A p.A436= | Silent (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.7533C>T p.D2511= (on ENST00000591111; = p.D2465= on NM_003319.4) | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as rs878878455, COSV60131009; ClinVar: likely benign; called by muse, mutect2
- TYRO3 | c.2076C>T p.S692= | Silent (SNP) | VAF 63/407 reads (15%) | catalogued as rs367718441; called by muse, mutect2, varscan2
- WDR33 | c.1999C>A p.R667= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV59249824; called by muse, mutect2, varscan2
- WDR72 | c.2229C>T p.A743= | Silent (SNP) | VAF 56/184 reads (30%) | called by muse, mutect2, varscan2
- WDR87 | c.7524C>T p.L2508= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- XIRP2 | c.1992C>A p.S664= (on ENST00000628543; = p.S839= on NM_152381.6) | Silent (SNP) | VAF 57/179 reads (32%) | called by muse, mutect2, varscan2
- ZFHX4 | c.9546C>G p.T3182= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as COSV99267926; called by muse, varscan2
- ZIC1 | c.375C>G p.A125= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- ZNF469 | c.11457C>A p.T3819= (on ENST00000437464; = p.T3847= on NM_001367624.2) | Silent (SNP) | VAF 40/206 reads (19%) | called by muse, mutect2, varscan2
- ZNF609 | c.778C>T p.L260= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV58591025; called by muse, mutect2, varscan2
- ZNF682 | c.478C>T p.L160= | Silent (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- ZNF804B | c.1284A>T p.V428= | Silent (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.3066G>A p.T1022= | Silent (SNP) | VAF 12/254 reads (5%) | catalogued as rs1251656131; ClinVar: likely benign; called by muse, mutect2
- AC005670.2 | chr17:47049790 C>A | 3'Flank (SNP) | VAF 110/627 reads (18%) | called by muse, mutect2, varscan2
- AC011410.1 | n.500G>A | RNA (SNP) | VAF 22/128 reads (17%) | catalogued as rs989250161; called by muse, mutect2, varscan2
- AC116903.1 | n.417+228T>C | Intron (SNP) | VAF 19/226 reads (8%) | called by muse, mutect2
- AC138123.1 | n.36C>A | RNA (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- ACSS1 | c.*852G>T | 3'UTR (SNP) | VAF 29/158 reads (18%) | called by muse, mutect2, varscan2
- ACTG2 | c.255+161G>A | Intron (SNP) | VAF 18/202 reads (9%) | catalogued as rs922950568; called by muse, mutect2
- ADAM6 | n.1096_1097insT | RNA (INS) | VAF 48/217 reads (22%) | called by mutect2, pindel*, varscan2
- ADPGK | chr15:72783841 G>T | 5'Flank (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2
- ALS2CL | c.1436+19C>A | Intron (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- BMERB1 | c.230+17620T>C | Intron (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- BTNL9 | c.887-35C>A | Intron (SNP) | VAF 37/349 reads (11%) | catalogued as rs1412286304; called by muse, mutect2, varscan2
- C16orf97 | n.75C>T | RNA (SNP) | VAF 26/139 reads (19%) | catalogued as rs1453214750; called by muse, varscan2
- C22orf34 | n.375G>T | RNA (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- C2orf49 | c.-19G>C | 5'UTR (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- CCDC183 | c.270+11A>T | Intron (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- CCSER1 | c.2217+239195G>T | Intron (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- CFB | c.2139+38G>A | Intron (SNP) | VAF 27/405 reads (7%) | called by muse, mutect2
- CHCHD2P9 | n.312A>T | RNA (SNP) | VAF 88/421 reads (21%) | catalogued as rs1280604175; called by muse, mutect2, varscan2
- CHMP1A | c.*35T>G | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2
- CHRAC1 | c.147+339G>T | Intron (SNP) | VAF 23/151 reads (15%) | called by muse, mutect2, varscan2
- COL4A6 | c.147+41657del | Intron (DEL) | VAF 20/95 reads (21%) | called by mutect2, pindel, varscan2
- CSMD3 | c.1030+56A>T | Intron (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- CYP4V2 | c.605-41G>C | Intron (SNP) | VAF 26/238 reads (11%) | called by muse, mutect2, varscan2
- DENND10P1 | n.878G>C | RNA (SNP) | VAF 148/313 reads (47%) | called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888366 G>A | 3'Flank (SNP) | VAF 86/326 reads (26%) | catalogued as rs764396320; called by mutect2, varscan2
- ERBB4 | c.82+112184A>T | Intron (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- FAM221B | c.*8C>A | 3'UTR (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- FBXL21P | n.550C>G | RNA (SNP) | VAF 14/105 reads (13%) | called by muse, mutect2, varscan2
60 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 60 other) are not listed here.
